Somatic mutation profile of tumor specimen TARGET-30-PASWVY-01A (aliquot TARGET-30-PASWVY-01A-01D) from TARGET case TARGET-30-PASWVY, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of abdomen; Age at diagnosis: 6.8 years (2,477 days).
Specimen TARGET-30-PASWVY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7544e268-d22f-4d06-96ce-02c214c1f43c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASWVY-10A (Blood Derived Normal), aliquot TARGET-30-PASWVY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a2b5360-e3bf-4d49-b5d9-f8ad257e0a32

The open-access MAF lists 49 somatic variants for this specimen: 36 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 32, Silent 13, Splice Region 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2ML1 | c.2137G>T p.E713* | Nonsense Mutation (SNP) | VAF 49/253 reads (19%) | catalogued as COSV55288211; called by muse, mutect2, varscan2
- ATP2A2 | c.2152G>A p.A718T | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV57875201; called by muse, mutect2, varscan2
- BICRAL | c.2605G>T p.V869L | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV58404507; called by muse, mutect2, varscan2
- CACNA1B | c.3802C>G p.L1268V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53120409; called by muse, mutect2
- CCDC183 | c.1134G>T p.M378I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.085); catalogued as COSV61034198; called by mutect2, varscan2
- CNTN4 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV68568140; called by muse, mutect2, varscan2
- CUL5 | c.560T>G p.L187R | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67608526; called by muse, mutect2
- DHTKD1 | c.2019G>C p.Q673H | Missense Mutation (SNP) | VAF 73/368 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV53802564, COSV53806590; called by muse, mutect2, varscan2
- EVA1C | c.918C>A p.S306R | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV55823474; called by muse, mutect2, varscan2
- FLNB | c.6755A>C p.Y2252S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55874695; called by muse, mutect2, varscan2
- GPR35 | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs775602865, COSV60576857; called by muse, mutect2, varscan2
- HSPG2 | c.5038G>A p.E1680K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs746299787, COSV65970297; called by muse, mutect2, varscan2
- LAMB2 | c.4337C>T p.A1446V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757984116, COSV59732149; called by muse, mutect2, varscan2
- LY75 | c.3270G>C p.Q1090H | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55103811; called by muse, mutect2, varscan2
- MAU2 | c.1221G>T p.R407= | Splice Region (SNP) | VAF 20/98 reads (20%) | catalogued as COSV53234519; called by muse, mutect2, varscan2
- NFATC1 | c.2603G>T p.C868F (on ENST00000427363 / NM_001278669.2; = p.C855F on NM_172387.3) | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as rs751771633, COSV53697656; called by muse, mutect2, varscan2
- OPLAH | c.277G>T p.G93W | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70677607; called by muse, mutect2, varscan2
- OR51G2 | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV58992320; called by muse, mutect2, varscan2
- OR5T1 | c.968T>C p.I323T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as COSV57302172; called by muse, mutect2
- PTPRH | c.767A>G p.N256S | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.96); PolyPhen benign (0.053); catalogued as COSV54744063; called by muse, mutect2, varscan2
- SELE | c.879C>A p.D293E | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60974629; called by muse, mutect2, varscan2
- SKIDA1 | c.2179G>C p.E727Q | Missense Mutation (SNP) | VAF 56/303 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.045); catalogued as COSV71610803; called by muse, mutect2, varscan2
- SLC14A2 | c.695A>T p.D232V | Missense Mutation (SNP) | VAF 58/301 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54907652; called by muse, mutect2, varscan2
- SLC19A3 | c.794G>T p.W265L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51452062; called by muse, mutect2, varscan2
- SPICE1 | c.2092G>T p.D698Y | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55619532; called by muse, mutect2, varscan2
- TASOR2 | c.4646G>A p.G1549E | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV60166603; called by muse, mutect2, varscan2
- WBP2NL | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 44/325 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as rs199835865; called by muse, mutect2, varscan2
- ZEB2 | c.2889A>C p.G963= | Splice Region (SNP) | VAF 6/18 reads (33%) | catalogued as COSV57954287; called by muse, mutect2
- COL8A1 | c.374A>G p.E125G | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.173); called by mutect2, varscan2
- CREBRF | c.1909T>A p.S637T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); called by muse, mutect2
- LMLN | c.1765C>A p.H589N | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2
- MED13 | c.2413T>C p.S805P | Missense Mutation (SNP) | VAF 12/297 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- PPFIBP2 | c.1387dup p.S463Kfs*11 | Frame Shift Ins (INS) | VAF 18/71 reads (25%) | called by mutect2, pindel, varscan2
- PPIAL4G | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- PTPRZ1 | c.6721C>G p.H2241D | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.285); called by muse, mutect2
- ZKSCAN8 | c.533C>A p.P178Q | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ANK2 | c.6633C>A p.A2211= | Silent (SNP) | VAF 17/78 reads (22%) | called by muse, mutect2, varscan2
- ATRN | c.2811A>T p.T937= | Silent (SNP) | VAF 31/156 reads (20%) | catalogued as COSV53525665; called by muse, mutect2, varscan2
- CEP162 | c.3333T>A p.L1111= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV57618804; called by muse, mutect2
- DZIP3 | c.2343C>T p.N781= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV64311597; called by muse, mutect2, varscan2
- FBN3 | c.6336C>T p.P2112= | Silent (SNP) | VAF 9/119 reads (8%) | called by muse, mutect2
- FOXA1 | c.1416C>G p.S472= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV51644956; called by muse, mutect2, varscan2
- LMO7 | c.789A>T p.T263= (on ENST00000357063; = p.T278= on NM_005358.5) | Silent (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- LRFN2 | c.2280C>T p.N760= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as rs749585155, COSV57824607; called by muse, mutect2, varscan2
- MRPS25 | c.282C>T p.S94= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV53741204; called by muse, mutect2, varscan2
- PARP14 | c.3729G>T p.V1243= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV71734337; called by muse, mutect2, varscan2
- RBM14 | c.891T>A p.A297= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV59558438; called by muse, mutect2, varscan2
- RYR1 | c.11397G>T p.L3799= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV62093452; called by muse, mutect2, varscan2
- SERPINA11 | c.1131C>T p.L377= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV58241480; called by muse, mutect2, varscan2
